TCGA case TCGA-AX-A3FX — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6f45a2e9-1ca5-438c-b06f-1cd8eb845465

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Dead; Days to death: 1,333 days (3.6 years).

Diagnoses (3)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 69.2 years (25,260 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIB; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,333 days (3.6 years).
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 2.
   Pathology details: Consistent pathology review: Yes.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 24.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Bevacizumab + Carboplatin + Paclitaxel; Days to treatment start: 939 days (2.6 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Carboplatin + Pegylated Liposomal Doxorubicin Hydrochloride; Days to treatment start: 1,255 days (3.4 years); Days to treatment end: 1,336 days (3.7 years).
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Endometrioid adenocarcinoma, NOS), site: Thorax, NOS. Age at diagnosis: 71.7 years (26,198 days); Days to diagnosis: 938 days (2.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
3. Recurrence of diagnosis 1 (Endometrioid adenocarcinoma, NOS), site: Thorax, NOS. Age at diagnosis: 72.5 years (26,492 days); Days to diagnosis: 1,232 days (3.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (3 entries)
- Day 938 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 938 days (2.6 years).
- Day 1,232 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 1,232 days (3.4 years).
- Follow-up contacts recording only the day: day 4, day 1,333.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85 kg; Height: 149 cm; BMI: 38.3.
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AX-A3FX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 100 mg.
  Slide TCGA-AX-A3FX-01A-01-TS1: Section location: Top; Percent tumor cells: 92; Percent tumor nuclei: 96; Percent normal cells: 5; Percent necrosis: 2; Percent stromal cells: 1; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-AX-A3FX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: TAH/BSO/LND/Panniculectomy; Surgical approach at diagnosis: open.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Pharmaceutical therapy drug name: Carboplatin/Paclitaxel/Bevacizumab.
- Drug treatment 2: Pharmaceutical therapy drug name: Doxil & Carboplatin.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,333 days; disease-specific survival: event status not recorded, 1,333 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 938 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AX-A3FX-01A-11D-A227-01): tumor purity 0.81, ploidy 1.98, whole-genome doublings 0.
